CCDI case PBBVPA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/c963c7a0-2b0f-490b-8fcb-c5a2c1415514

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/0; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 10.9 years (3,980 days).

Biospecimens (3 samples)
- Sample 0DIPKL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIPLB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DIPLL: Tissue type: Tumor; Specimen type: Solid Tissue.
